Surgical pathology report (de-identified scan), TCGA case TCGA-46-3768, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site St. Joseph's Medical Center (MD), specimen TCGA-46-3768-01A (Primary Tumor).

[page 1 of 4]
PRIORITY: FROZEN SEC

SURGICAL PROCEDURES:

RESECTION, REGIONAL LYMPH

CLINICAL HISTORY

OTHER SPECIAL CONSULTATION: TCGA STUDY.

PERTINENT CLINICAL HISTORY: LEFT UPPER LOBE CA.

OPERATIVE FINDINGS: LEFT THORACOSCOPIC LOBECTOMY.

GROSS DESCRIPTION

A. The specimen is submitted fresh for frozen section as "level 5" and consists of a red black node measuring 0.8 cm in greatest dimension. The specimen is submitted in toto, 1 (1) labeled "FSP" and used for frozen section.

FROZEN SECTION DIAGNOSIS: Negative for tumor. [REDACTED]

B. The specimen is submitted fresh for frozen section as "level 8 left lower (FS #2)" and consists of a red black node measuring 0.5 cm in greatest dimension. The specimen is submitted in toto, 1 (1) labeled "FSP" and used for frozen section.

FROZEN SECTION DIAGNOSIS: Negative for tumor. [REDACTED]

C. The specimen is submitted fresh as "left upper lobe - please ink pleural margins" and consists of a 448 gm (formalin fixed), 22 x 15 x 9 cm lung lobectomy specimen received with a stapled bronchial margin measuring 2 cm in diameter x 1 cm in length, multiple stapled vasculature margins measuring 0.5 cm in length x 1 cm in diameter to 0.6 cm in length x 1.5 cm in diameter and multiple stapled surgical margin measuring 1.5 cm in width x 5 cm in length. The pleural surface shows a tan brown ragged disrupted area with an underlying diffusely firm nodular mass. The pleural surface overlying the mass is inked blue. The stapled resection margins are

[page 2 of 4]
GROSS DESCRIPTION

(Continued)

removed and the underlying parenchyma is inked black. Sectioning reveals an 8 x 6.8 x 6.2 cm well circumscribed gray tan to white firm focally fleshy mass which grossly appears to abut the blue inked overlying pleural surface measuring 0.8 cm from the closest black inked parenchyma underlying the stapled resection margin and 1.7 cm from the bronchial margin at the hilum. The remaining parenchyma consists of pink red spongy homogenous and grossly unremarkable tissue. No other discrete masses or nodularities are grossly identified. At the hilum are multiple gray tan to white firm matted lymph nodes measuring 0.5 cm to 1.5 cm in greatest dimension. Representative sections of the matted nodes along with representative sections of the specimen are submitted; multiple (9) as follows:

Cassette 1:	Vasculature and bronchial resection margins.
Cassette 2-3:	Mass closest to blue inked pleural surface.
Cassette 4:	Perpendicular section of mass to closest black inked parenchyma underlying the stapled resection margin.
Cassette 5:	Perpendicular section of the hilum closest to mass.
Cassette 6:	Uninvolved parenchyma and pleural surface.
Cassette 7-8:	Representative sections of the matted nodes at hilum.
Cassette 9:	One hilar lymph node, bisected.

D. The specimen is submitted fresh as "neck of 6th rib" and consists of a segment of rib measuring 2 cm in length and 1.5 cm in diameter. Representative longitudinal sections are submitted, 3 (1) for decalcification.

E. The specimen is submitted fresh as "neck of 5th rib" and consists of two segments of rib measuring 1.5 and 2 cm in length and 0.7 cm each in diameter. The pieces are friable and disrupted. The specimen is sectioned longitudinally and submitted in toto, 4 (1) for decalcification.

F. The specimen is submitted fresh as "posterior hilar node" and consists of two firm red tan nodules measuring 1 and 1.5 cm each in dimension. Sectioning of each reveals friable gray black tissue. Each is bisected and the specimen submitted in toto, 2 (1).

G. The specimen is submitted fresh as "anterior hilar node" and consists of a red black node measuring 2 x 1.5 x 0.5 cm. The specimen is bisected and submitted in toto, 2 (1).

[page 3 of 4]
FINAL DIAGNOSIS

- A. LYMPH NODE, LEVEL 5, EXCISION:
- LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- B. LYMPH NODE, LEVEL 8 LEFT LOWER, EXCISION:
- LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- C. LUNG, LEFT UPPER LOBE, LOBECTOMY:
- INVASIVE SQUAMOUS CELL CARCINOMA. . SEE SYNOPTIC REPORT.
- D. NECK OF 6TH RIB, RESECTION:
- BENIGN RIB BONE.
- E. NECK OF 5TH RIB, RESECTION:
- BENIGN RIB BONE.
- F. LYMPH NODE, POSTERIOR HILAR, EXCISION:
- METASTATIC CARCINOMA INVOLVING TWO OF TWO NODES (2/2).
- G. LYMPH NODE, ANTERIOR HILAR, EXCISION:
- LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

SYNOPTIC REPORT

SYNOPTIC REPORT: LUNG
(CAP/AJCC/ACS - REQUIRED ELEMENTS)

SPECIMEN TYPE: LOBECTOMY
LATERALITY: LEFT
TUMOR SITE: LEFT UPPER LOBE
TUMOR SIZE: 8 CM
HISTOLOGIC TYPE: SQUAMOUS
HISTOLOGIC GRADE: G2-3 OF 4 (MODERATELY TO POORLY DIFFERENTIATED)
EXTENT OF INVASION: EXTENDS TO PARIETAL PLEURA
EXTENSION TO PLEURA/OTHER STRUCTURES: PARIETAL PLEURA

[page 4 of 4]
SYNOPTIC REPORT

(Continued)

BRONCHIAL: UNINVOLVED
PARENCHYMAL: UNINVOLVED
VASCULAR: UNINVOLVED
CHEST WALL: UNINVOLVED

DISTANCE TO PERTINENT MARGIN(S): 0.8 CM FROM THE PARENCHYMAL MARGIN

VENOUS INVASION: NOT DEFINITELY IDENTIFIED

ARTERIAL (LARGE VESSEL) INVASION: NOT DEFINITELY IDENTIFIED

LYMPH NODE:

f, , , , N1 - # INVOLVED/# EXAMINED: 5/8

f, , , , N2 - # INVOLVED/#EXAMINED: 0/7+

f, , , , N3 - # INVOLVED/# EXAMINED: 0/0

OTHER PERTINENT FINDINGS:

- THE TUMOR IS ADHERENT TO AND FOCALLY INVADES PARIETAL PLEURA BUT DOES NOT INVADE FAT, SKELETAL MUSCLE, OR NERVE BUNDLE.
- REMAINING LUNG SHOWS EMPHYSEMATOUS CHANGES.
- THREE POSITIVE PERIHILAR LYMPH NODES ARE IDENTIFIED ON THE LOBECTOMY SPECIMEN.

pTNM STAGE: pT3 N1 (AJCC 7TH EDITION)

Source: NCI Genomic Data Commons file 945ce3e6-1abf-400d-ba51-fd8abb91f70d (TCGA-46-3768.83E30A4B-4DF4-41D8-AA7C-7AE95BE3B9FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).